Somatic mutation profile of tumor specimen TCGA-ZG-A9LM-01A (aliquot TCGA-ZG-A9LM-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9LM, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.2 years (26,377 days).
Specimen TCGA-ZG-A9LM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) beff6a44-ccf6-4951-9b7f-3fd462b8b864.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9LM-10A (Blood Derived Normal), aliquot TCGA-ZG-A9LM-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51e53d51-f1a4-4e2a-83a3-6fa913166784

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 9, Nonsense Mutation 5, RNA 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP2B2 | c.1783C>T p.R595C (on ENST00000352432; = p.R561C on NM_001683.5) | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776463160, COSV59494867; called by muse, mutect2, varscan2
- CYP4F3 | c.514A>G p.N172D | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.03); catalogued as COSV99657969; called by muse, mutect2, varscan2
- EEF1AKNMT | c.761G>A p.W254* (on ENST00000361735 / NM_015935.5; = p.W168* on NM_014955.3) | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as rs1448223764, COSV100675802; called by muse, mutect2, varscan2
- EIF2S1 | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.685); catalogued as COSV99371638; called by muse, mutect2, varscan2
- GOLGA4 | c.3016A>G p.M1006V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV100728745; called by muse, mutect2, varscan2
- HTR1E | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs771278269, COSV59507451; called by muse, mutect2, varscan2
- IGLV3-22 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as rs569134161; called by muse, mutect2, varscan2
- IL24 | c.210G>A p.W70* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as rs757703371, COSV54321295, COSV99686403; called by muse, mutect2, varscan2
- ITGAM | c.1279C>T p.Q427* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99792001; called by muse, mutect2, varscan2
- ITPRIPL1 | c.688C>T p.H230Y (on ENST00000439118 / NM_001008949.3; = p.H238Y on NM_178495.6) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV100742166; called by muse, mutect2, varscan2
- MET | c.3973G>A p.E1325K | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs587778444, COSV59264985; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- MIDEAS | c.1789G>A p.V597M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs141337993; called by muse, mutect2, varscan2
- MSGN1 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99808705; called by muse, mutect2, varscan2
- NUP133 | c.1099C>T p.L367F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV99772734; called by muse, mutect2
- PGM2 | c.1226C>G p.A409G | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as COSV101126556; called by muse, mutect2, varscan2
- PMEL | c.305T>A p.V102D | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100656963; called by muse, mutect2, varscan2
- PSMC1 | c.929T>C p.L310S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99728220; called by muse, mutect2, varscan2
- RIC8A | c.200T>A p.L67Q | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100254743; called by muse, mutect2, varscan2
- RUNX3 | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1280209983, COSV100136735; called by muse, mutect2, varscan2
- UBXN11 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100122498; called by muse, mutect2, varscan2
- DMTF1 | c.651_653del p.M217_Y218delinsI | In Frame Del (DEL) | VAF 11/107 reads (10%) | called by mutect2, pindel
- FBLN1 | c.1240_1243del p.K414Afs*116 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- CENPF | c.1515G>A p.L505= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV100871591; called by muse, mutect2, varscan2
- COL21A1 | c.690A>G p.G230= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV55178392, COSV99777949; called by muse, mutect2, varscan2
- EXOC1 | c.165C>T p.V55= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs777928670, COSV100637781; called by muse, mutect2, varscan2
- FIBIN | c.111C>T p.F37= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs747999392, COSV100590387; called by muse, mutect2, varscan2
- ITPKB | c.1299C>T p.G433= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs550313561, COSV55269114; called by muse, mutect2, varscan2
- LPIN2 | c.282A>G p.E94= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- MFRP | c.138G>A p.G46= (on ENST00000449574; = p.G422= on NM_031433.4) | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100793378; called by muse, mutect2, varscan2
- NOX1 | c.1428A>G p.G476= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV99471502; called by muse, mutect2, varscan2
- ZNF318 | c.2028A>G p.L676= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV100546042; called by muse, mutect2, varscan2
- RRM2 | n.627G>A | RNA (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
